Gene-level copy-number profile of tumor specimen C3L-06424-02 from CPTAC case C3L-06424, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.2 years (25,996 days).
Specimen C3L-06424-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Back; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f56ed597-172b-41f9-8cb3-46a61b509cad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06424-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/f75f5596-2b36-4138-aaa4-453c9886d7fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 704; copy number 2: 4,221; copy number 3: 2,068; copy number 4: 38,329; copy number 5: 2,733; copy number 6: 5,620; copy number 7: 1,668; copy number 8: 1,037; copy number 10: 2,050; copy number 11: 9; copy number 12: 458; copy number 13: 7; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,527 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,508,806, 3 genes, copy number 15: AC119751.3, ANKRD20A17P, AC119751.5.
- chr5:75,336,329–80,876,815, 119 genes, copy number 12–13 (within-gene range 7–13) (broad region; genes not listed).
- chr5:83,637,805–84,384,880, 7 genes, copy number 11 (within-gene range 7–11): HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1, EDIL3.
- chr5:84,999,812–108,728,260, 268 genes, copy number 12 (broad region; genes not listed).
- chr5:109,588,338–109,688,329, 2 genes, copy number 11–13: KRT18P42, MAN2A1-DT.
- chr5:110,289,233–113,022,195, 44 genes, copy number 12 (within-gene range 2–12): TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1, NREP, RN7SKP57, HMGN1P14, NREP-AS1, EPB41L4A, EPB41L4A-AS1, SNORA13, AC010261.1, AC010261.2, AC104126.1, AC010265.1, EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2.
- chr5:116,443,555–117,038,569, 9 genes, copy number 11–12: SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2.
- chr5:118,836,074–119,070,902, 7 genes, copy number 12 (within-gene range 3–12): DTWD2, PTMAP2, MIR1244-2, AC008629.1, RNU6-373P, AC008629.2, AC008629.3.
- chr5:122,628,952–123,637,403, 18 genes, copy number 12: LINC02201, ARGFXP1, SNX2, AC008669.1, SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1, CEP120, KRT8P33, HMGB3P17, AC026422.1, CSNK1G3, KRT18P16.
- chr5:173,225,836–181,342,213, 263 genes, copy number 10 (broad region; genes not listed).
- chr7:65,023,204–159,233,377, 1,787 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
